Somatic mutation profile of tumor specimen ALCH-B2AR-TTP1-A (aliquot ALCH-B2AR-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.7 years (27,298 days).
Specimen ALCH-B2AR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc599091-b291-4f15-a6cc-c239d4ddae62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AR-NB1-A (Blood Derived Normal), aliquot ALCH-B2AR-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f3f4a5e-30bf-4413-be12-f73ad357faab

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 62/506 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD3 | c.799G>A p.D267N (on ENST00000396553 / NM_001025389.2; = p.D276N on NM_000480.3) | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.105); catalogued as rs140837736; called by muse, mutect2, varscan2
- ANKRD11 | c.3914C>G p.S1305C | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV56366710; called by muse, mutect2
- DNAI1 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs751197523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR139 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032845174, COSV58503205; called by muse, mutect2
- OPLAH | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs531006889, COSV70679452; called by muse, mutect2
- SBNO2 | c.4073C>T p.P1358L | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1439591026; called by muse, mutect2
- ACTRT3 | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- COPG1 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- MAST4 | c.809C>A p.S270* (on ENST00000403625 / NM_001164664.2; = p.S81* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 21/454 reads (5%) | called by muse, mutect2
- NUP210L | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR2D2 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PRR14L | c.1882A>G p.I628V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2
- SFTPB | c.1084-12_1085del p.X362_splice | Splice Site (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel
- TNS3 | c.3232A>G p.S1078G | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC2 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- URAD | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- WDFY3 | c.10418G>T p.R3473L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AHCTF1 | c.4500C>T p.L1500= (on ENST00000366508; = p.L1474= on NM_015446.5) | Silent (SNP) | VAF 18/221 reads (8%) | catalogued as COSV58245829; called by muse, mutect2
- CCR4 | c.114G>A p.G38= | Silent (SNP) | VAF 61/346 reads (18%) | called by muse, mutect2, varscan2
- COL6A1 | c.1227G>A p.A409= | Silent (SNP) | VAF 18/314 reads (6%) | catalogued as rs557250335, COSV100720144; ClinVar: likely benign; called by muse, mutect2
- KIAA0319 | c.2565G>A p.Q855= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- KIRREL3 | c.60G>A p.L20= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- LILRA1 | c.1407C>T p.G469= | Silent (SNP) | VAF 26/402 reads (6%) | catalogued as COSV99252272; called by muse, mutect2
- PRDM16 | c.108C>T p.D36= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs770557050, COSV54592308; ClinVar: likely benign; called by muse, mutect2
- RELL2 | c.237C>A p.I79= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- DDX27 | c.1887+21C>G | Intron (SNP) | VAF 45/387 reads (12%) | catalogued as rs778578935; called by muse, mutect2, varscan2
- GNG7 | c.-78+3391C>T | Intron (SNP) | VAF 25/342 reads (7%) | called by muse, mutect2
